Somatic mutation profile of tumor specimen C3N-01897-01 (aliquot CPT0162300019) from CPTAC case C3N-01897, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 56.1 years (20,477 days).
Specimen C3N-01897-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85171c9f-b150-4469-89b9-13f42c9c103b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01897-31 (Blood Derived Normal), aliquot CPT0162360002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ece1f50-3166-416d-bb8f-2cd29e46d9ac

The open-access MAF lists 38 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 7, Intron 5, Splice Site 2, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 183/904 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.559+1G>A p.X187_splice | Splice Site (SNP) | VAF 286/951 reads (30%) | hotspot (GDC flag); catalogued as rs1131691042, CS137624, COSV52670017, COSV52686439, COSV52695669; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASIC2 | c.504G>A p.M168I | Missense Mutation (SNP) | VAF 81/460 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs376380924; called by muse, mutect2, varscan2
- CACNA2D1 | c.739G>T p.G247* | Nonsense Mutation (SNP) | VAF 22/571 reads (4%) | catalogued as rs1554385483, COSV62374580; called by muse, mutect2
- DAXX | c.1909A>C p.K637Q | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs200527264; called by muse, mutect2, varscan2
- FLT4 | c.1904C>T p.T635M | Missense Mutation (SNP) | VAF 74/281 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs753863393, COSV56117471; called by muse, mutect2, varscan2
- HMCN1 | c.9989G>A p.R3330Q | Missense Mutation (SNP) | VAF 224/1052 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs780529619, COSV54878805; called by muse, mutect2, varscan2
- HRH4 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 179/864 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.202); catalogued as rs775040150; called by muse, mutect2, varscan2
- KCNA3 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 193/717 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100871329; called by muse, mutect2, varscan2
- MUC16 | c.9329C>T p.T3110I | Missense Mutation (SNP) | VAF 34/896 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs953662879; called by muse, mutect2
- NFATC2 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 281/1335 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1234960228, COSV65355992, COSV65356510; called by muse, mutect2, varscan2
- RGSL1 | c.13+2T>C p.X5_splice | Splice Site (SNP) | VAF 57/1145 reads (5%) | catalogued as rs757002703; called by muse, mutect2
- TKTL1 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 246/574 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs201452569; called by muse, mutect2, varscan2
- UNC5A | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 68/308 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779405939; called by muse, mutect2, varscan2
- XDH | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 258/2019 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs140879910; called by muse, mutect2, varscan2
- ASIC2 | c.505C>A p.L169I | Missense Mutation (SNP) | VAF 77/446 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATP6V0A1 | c.1598A>T p.N533I | Missense Mutation (SNP) | VAF 65/297 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATXN7 | c.1354C>T p.L452F | Missense Mutation (SNP) | VAF 28/802 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.799); called by muse, mutect2
- CCNA1 | c.995T>A p.L332Q | Missense Mutation (SNP) | VAF 56/1357 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLEC18C | c.375C>G p.S125R | Missense Mutation (SNP) | VAF 200/3201 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.09); called by muse, mutect2
- DAPK1 | c.3311C>T p.P1104L | Missense Mutation (SNP) | VAF 84/607 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DCAF12L2 | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 334/810 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.071); called by muse, varscan2
- LCE2B | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 26/655 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PEAR1 | c.1913A>G p.Y638C | Missense Mutation (SNP) | VAF 178/897 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- RSBN1 | c.2074G>T p.V692L | Missense Mutation (SNP) | VAF 16/558 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- GTF2F1 | c.528C>T p.I176= | Silent (SNP) | VAF 42/419 reads (10%) | catalogued as rs958981391; called by muse, mutect2
- HTT | c.1752C>T p.D584= | Silent (SNP) | VAF 200/972 reads (21%) | catalogued as rs368866386; called by muse, mutect2, varscan2
- KLHL29 | c.87C>T p.T29= | Silent (SNP) | VAF 198/839 reads (24%) | called by muse, mutect2, varscan2
- KRT37 | c.648C>T p.D216= | Silent (SNP) | VAF 206/882 reads (23%) | catalogued as rs766404637, COSV56658723; called by muse, mutect2, varscan2
- PCDHA9 | c.1662C>T p.F554= | Silent (SNP) | VAF 632/2786 reads (23%) | catalogued as rs782760687, COSV65329339; called by muse, mutect2, varscan2
- SNTG2 | c.45C>G p.R15= | Silent (SNP) | VAF 17/82 reads (21%) | called by muse, mutect2, varscan2
- TMEM131L | c.4620G>A p.P1540= | Silent (SNP) | VAF 237/818 reads (29%) | catalogued as rs375188134; called by muse, mutect2, varscan2
- CDK14 | c.124-16967del | Intron (DEL) | VAF 155/737 reads (21%) | called by mutect2, pindel, varscan2
- CKS1B | c.59+82G>C | Intron (SNP) | VAF 196/951 reads (21%) | called by muse, mutect2, varscan2
- MPRIP | c.2163+4739G>A | Intron (SNP) | VAF 49/210 reads (23%) | catalogued as rs560323745, COSV100506137; called by muse, mutect2, varscan2
- RAB3IP | c.936+28A>T | Intron (SNP) | VAF 103/422 reads (24%) | called by mutect2, varscan2
- TCP10L3 | n.2719+1079G>C | Intron (SNP) | VAF 225/1429 reads (16%) | catalogued as rs772225714; called by muse, mutect2, varscan2
- UAP1L1 | chr9:137086488 G>A | 3'Flank (SNP) | VAF 108/392 reads (28%) | called by muse, mutect2, varscan2
